Somatic mutation profile of tumor specimen MP2PRT-PAVZIN-TMP1-A (aliquot MP2PRT-PAVZIN-TMP1-A-1-0-D-A81A-36) from MP2PRT case MP2PRT-PAVZIN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (946 days).
Specimen MP2PRT-PAVZIN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c905635-024b-402a-a50f-fa894575f21e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVZIN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVZIN-NB1-A-1-0-D-A81A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ba37b0e-f5e8-462b-b905-ec67c183f5a1

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FSD1 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 46/458 reads (10%) | called by muse, mutect2
- PANX3 | c.723C>A p.S241R | Missense Mutation (SNP) | VAF 17/406 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.343); called by muse, mutect2
- PCDHGA5 | c.1112T>A p.V371E | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2
